Somatic mutation profile of tumor specimen TCGA-14-0865-01B (aliquot TCGA-14-0865-01B-01W-0643-08) from TCGA case TCGA-14-0865, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.9 years (24,797 days).
Specimen TCGA-14-0865-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c1fb9b7-847e-4c33-98b4-8b48b3d1fb4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-0865-10A (Blood Derived Normal), aliquot TCGA-14-0865-10A-01W-0643-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25ae6f57-797a-4fdd-a293-dc0efa1db330

The open-access MAF lists 54 somatic variants for this specimen: 42 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMBN | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59826888; called by muse, mutect2, varscan2
- ANK2 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52167366; called by muse, mutect2, varscan2
- AP1M1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.772); catalogued as COSV99358374; called by muse, mutect2, varscan2
- ATP9A | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444128345, COSV100124935; called by muse, mutect2, varscan2
- CILK1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 220/373 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs901020533, COSV63153887; called by muse, varscan2
- CNOT7 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 159/375 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs1453783166, COSV63517936; called by muse, mutect2, varscan2
- DIS3 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201674523, COSV66706858; called by muse, mutect2, varscan2
- DNAH11 | c.8864T>C p.V2955A | Missense Mutation (SNP) | VAF 263/687 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.492); catalogued as COSV100179193; called by muse, mutect2, varscan2
- DTX2 | c.1052G>A p.C351Y | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV56862300; called by muse, mutect2, varscan2
- EPCAM | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs538099447, COSV55393529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLAD1 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 12/322 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV99422477; called by muse, mutect2
- HCLS1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 145/273 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs144589441; called by muse, mutect2, varscan2
- KIR2DL1 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 37/371 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs553029013, COSV52406038; called by muse, mutect2, varscan2
- KIR2DL3 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 62/920 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as rs746107872, COSV100668026; called by muse, mutect2
- KRTAP10-7 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs782308706, COSV100170132; called by muse, mutect2, varscan2
- LDHA | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 172/233 reads (74%) | catalogued as COSV57041031; called by muse, mutect2, varscan2
- NF2 | c.1018G>C p.A340P | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.651); catalogued as CD115314; called by mutect2, varscan2
- NFIA | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); catalogued as COSV100783313; called by muse, mutect2
- OXSM | c.769A>T p.N257Y | Missense Mutation (SNP) | VAF 178/418 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774471689, COSV55001981; called by muse, mutect2, varscan2
- PARP9 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376922210, COSV64450352; called by muse, mutect2
- PDGFRA | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 484/548 reads (88%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV57265161; called by muse, varscan2
- PPP4R1 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.641); catalogued as COSV53282668; called by muse, mutect2, varscan2
- RAD51AP2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV67588443; called by muse, mutect2, varscan2
- RIMS2 | c.3134G>A p.R1045Q (on ENST00000666250 / NM_001348490.2; = p.R853Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 333/617 reads (54%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as rs776394480, COSV51665828; called by muse, mutect2, varscan2
- RYR2 | c.5836G>A p.E1946K | Missense Mutation (SNP) | VAF 205/726 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.31); catalogued as rs267598436, COSV63689111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6D | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 21/605 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV100316950; called by muse, mutect2
- SH2B2 | c.258C>A p.C86* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100159374; called by muse, mutect2
- SRSF11 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.931); catalogued as COSV100917913, COSV63937820; called by muse, mutect2, varscan2
- TCHH | c.1581G>C p.R527S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | PolyPhen benign (0.081); catalogued as COSV64275804; called by muse, mutect2, varscan2
- TNNT2 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 241/593 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV52663613; called by muse, mutect2, varscan2
- TRAPPC6B | c.352-2A>T p.X118_splice (on ENST00000330149 / NM_001079537.2; = p.X90_splice on NM_177452.4) | Splice Site (SNP) | VAF 4/44 reads (9%) | catalogued as COSV57528429; called by mutect2, varscan2
- TTN | c.86332G>T p.A28778S (on ENST00000591111; = p.A21354S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/542 reads (3%) | PolyPhen probably damaging (0.996); catalogued as COSV100611760; called by muse, mutect2
- UHRF1BP1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1025338905, COSV51957315; called by muse, mutect2, varscan2
- YLPM1 | c.2491C>T p.R831* | Nonsense Mutation (SNP) | VAF 208/311 reads (67%) | catalogued as rs764707969, COSV99458350; called by muse, mutect2, varscan2
- ZDHHC23 | c.685A>G p.M229V | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV57629777; called by muse, mutect2, varscan2
- ZNF212 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745987143, COSV60025155; called by muse, mutect2, varscan2
- ZNF875 | c.831G>C p.E277D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV100183314; called by muse, mutect2, varscan2
- EXPH5 | c.1942A>T p.N648Y | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- NSD3 | c.759dup p.L254Tfs*14 | Frame Shift Ins (INS) | VAF 98/278 reads (35%) | called by mutect2, pindel, varscan2
- PEX1 | c.2272G>C p.D758H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by mutect2, varscan2
- PPP1R8 | c.186del p.I62Mfs*19 | Frame Shift Del (DEL) | VAF 69/313 reads (22%) | called by mutect2, pindel, varscan2
- TPTE | c.1003G>A p.A335T (on ENST00000618007 / NM_199261.4; = p.A317T on NM_199259.4) | Missense Mutation (SNP) | VAF 204/1112 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DICER1 | c.4698G>C p.L1566= | Silent (SNP) | VAF 148/339 reads (44%) | catalogued as rs372837448, COSV100602024; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM83B | c.1890C>T p.G630= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- HCN1 | c.2229G>A p.P743= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV57510678; called by muse, mutect2, varscan2
- HELB | c.3144T>C p.S1048= | Silent (SNP) | VAF 54/289 reads (19%) | catalogued as COSV99921898; called by muse, mutect2, varscan2
- IL16 | c.2631G>A p.K877= (on ENST00000302987 / NM_172217.5; = p.K176= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as COSV57265305; called by muse, mutect2, varscan2
- IL1RAPL2 | c.960A>T p.S320= | Silent (SNP) | VAF 377/404 reads (93%) | catalogued as COSV61165031; called by muse, mutect2, varscan2
- OSCP1 | c.645C>T p.L215= (on ENST00000356637 / NM_001330493.1; = p.L205= on NM_145047.5) | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99347266; called by muse, varscan2
- PIK3CG | c.426G>A p.P142= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs747872159, COSV63248555; called by muse, mutect2, varscan2
- PKD1L2 | c.1149G>A p.V383= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100449866; called by muse, mutect2, varscan2
- SPTA1 | c.2253A>G p.A751= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1359108066, COSV63755757; called by muse, mutect2, varscan2
- ZFP42 | c.792G>A p.T264= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs781591825, COSV58818064; called by muse, varscan2
- MIR525 | n.49A>C | RNA (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2, varscan2
